Surgical pathology report (de-identified scan), TCGA case TCGA-H7-7774, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-H7-7774-01A (Primary Tumor).

[page 1 of 9]
Operative Procedure:

Right neck dissection, right superficial parotidectomy, right mandible composite resection, partial glossectomy, right tonsillectomy and possible left neck dissection.

Specimen Received:

- A: Right level 1B and level 1A
- B: Right perifacial lymph node
- C: Right mandible composite resection (margins to be taken from patient) single stitch right basilar tongue, double stitch right anterior buccal
- D: Right buccal fat pad
- E: Right sublingual gland
- F: Dorsal tongue margin
- G: Right floor of mouth margin
- H: Anterior gingival margin
- I: Anterior buccal margin
- J: Soft palate margin
- K: Superior lip
- L: Deep tongue margin
- M: Maxillary alveolar ridge
- N: Glosso tonsilar sulcus
- O: Right deep buccal margin
- P: Right temporalis margin
- Q: Medial pterygoid margin
- R: Right parotid mass
- S: Maxillary bone
- T: Right neck dissection, single stitch level 2

Final Pathologic Diagnosis:

Synoptic Report

Right mandibular composite resection:

Papillary keratinizing squamous cell carcinoma, moderately differentiated.

Histologic type/grade: Papillary keratinizing squamous cell carcinoma, moderately differentiated

Tumor size: 8 cm (greatest dimension)

Depth of invasion: 0.7 cm (greatest dimension)

Lymph-vascular invasion: Not identified

Perineural invasion: Not identified

Tumor site: Buccal mucosa to tongue

Tumor focality: Single focus

Margins:

Margins uninvolved by invasive carcinoma

Distance from closest margin: 0.4 cm

[page 2 of 9]
Specify margin(s), per orientation: Base of tongue area

Margins uninvolved by carcinoma in situ

Distance from closest margin: 0.4 cm

Specify margin(s), per orientation: Posterior buccal mucosa
retromolar region

Lymph nodes, extranodal extension: Right level I-IV, no evidence of
malignancy (0 of 21 lymph nodes positive)

Pathologic Staging (pTNM):

TNM descriptors:

Primary tumor (pT): pT4

Regional lymph nodes (pN): pN0

Number examined: 21

Number involved: 0

Distant metastasis (pM): pM0 (clinical assessment)

Additional pathologic findings: Tumor erodes mandibular cortex but does not
invade medullary component

Specimen: Buccal mucosa retromolar, lateral tongue and
mandible

Received: In formalin

Procedure: Composite resection, partial mandibulectomy
with buccal mucosa resection, right neck dissection

Specimen size: 9 x 4.5 x 2 cm

Specimen laterality: Right

A. Right level IB and IA, lymph node dissection:

No evidence of malignancy (0 of 3 lymph nodes positive).

Submandibular gland exhibiting no pathologic change.

B. Right perifacial lymph node, biopsy:

No evidence of malignancy (0 of 2 lymph nodes positive).

C. Right mandible, composite resection:

Papillary keratinizing squamous cell carcinoma, moderately differentiated
(see Synoptic Report for details).

D. Right buccal fat pad [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

E. Right sublingual gland [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

F. Dorsal tongue margin [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

[page 3 of 9]
G. Right floor of mouth margin [REDACTED]

Mild epithelial dysplasia, no evidence of high grade dysplasia, carcinoma in situ or invasion, frozen section diagnosis confirmed.

H. Anterior gingival margin [REDACTED]

Mild epithelial dysplasia, no evidence of high grade dysplasia, carcinoma in situ or invasion, frozen section diagnosis confirmed.

I. Anterior buccal margin [REDACTED]

Mild epithelial dysplasia, no evidence of high grade dysplasia, carcinoma in situ or invasion, frozen section diagnosis confirmed.

J. Soft palate margin [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

K. Superior lip [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

L. Deep tongue margin [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

M. Maxillary alveolar ridge, biopsy [REDACTED]

No evidence of malignancy (scant epithelium present on frozen and permanent sections, frozen section diagnosis confirmed).

N. Glossal tonsillar sulcus [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

O. Right deep buccal margin [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

P. Right temporalis margin [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

Q. Medial pterygoid margin [REDACTED]

No evidence of malignancy, frozen section diagnosis confirmed.

R. Right parotid mass, excision [REDACTED]

Dermal cylindroma, surgical margins free of neoplasia, frozen section diagnosis confirmed.

S. Maxillary bone, biopsy:

No evidence of malignancy.

T. Right neck dissection, levels II-IV:

No evidence of malignancy (0 of 16 lymph nodes positive).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

[page 4 of 9]
Intraoperative Consult Diagnosis:

FSD: Right buccal fat pad:

Negative for malignancy.

FSE: Right sublingual gland:

Negative for malignancy.

FSF: Dorsal tongue margin:

Negative for malignancy.

FSG: Right floor of mouth margin:

Negative for malignancy.

FSH: Anterior gingival margin:

Negative for malignancy.

FSI: Anterior buccal margin:

Negative for malignancy.

FSJ: Soft palate margin:

Negative for malignancy.

FSK: Superior lip:

Negative for malignancy.

FSL: Deep tongue margin:

Negative for malignancy.

FSM: Maxillary alveolar ridge:

Negative for malignancy.

FSN: Glossal tonsillar sulcus:

Negative for malignancy.

FSO: Right deep buccal margin:

Negative for malignancy.

FSP: Right temporalis margin:

Negative for malignancy.

FSQ: Medial pterygoid margin:

Negative for malignancy.

FSR: Right parotid mass:

Ecrrine dermal cylindroma.

Gross Description:

Received are twenty specimen containers all labeled with the patient's name.

Parts D through part R are all received fresh for frozen section evaluation with parts A through C, S and T received in formalin.

Part A is received additionally labeled "right level 1B and level 1A" and consists of a single portion of pink-tan to yellow soft tissue consisting of an apparent salivary gland, which is 4 x 3.2 x 1.3 cm with an additional attached fibrofatty tissue, which are 3 x 2 x 1.1 cm. Step sectioning the salivary gland component reveals the usual tan lobulated architecture without distinct mass. There are no intraparenchymal lymph nodes grossly identified. Representative section of the salivary gland is submitted in cassette A1. Within the associated fibrofatty tissues there are four probable lymph nodes, which range from 0.2 to 1.3 cm in greatest dimension, none of which appear involved by

[page 5 of 9]
tumor, which are submitted as follows:

- A2 one whole probable lymph node;
- A3 three whole probable lymph nodes.

Part B is received additionally labeled "rightperifacial lymph node" and consists of a single portion of pink-tan nodular and yellow lobulated soft tissue, all of which have aggregate dimensions of 2 x 1.4 x 0.8 cm. Examination of these tissues confirms the presence of two probable lymph nodes, 0.3 and 1.8 cm in greatest dimension, neither of which appear to have tumor involvement. These lymph node candidates are submitted as follows:

- B1 one whole probable lymph node;
- B2 one whole probable lymph node bisected.

Part C is received additionally labeled "right mandible composite resection (margins taken from patient), single stitch margin right basilar tongue, double stitch right anterior buccal." This composite specimen has aggregate dimensions of 9 x 6 x 5 cm and consists of a partial resection of mandible, having dimensions of 6 x 4.5 x 0.9 cm with associated adherent soft tissue, surfaced by mucosa to include right buccal wall region of trigone, floor of mouth and approaching base of tongue. This soft tissue component has dimensions of 9 x 4.5 by up to 2 cm (base of tongue).

The cut surfaces of the soft tissue component are inked in the following manner:

Base of tongue black (region of single suture), perimandibular tissues and region approaching trigone pharyngeal wall blue.

The mucosa of the specimen is remarkable for an area of probable leukoplakia, 3.5 x 2 cm with areas that are slightly raised up to 0.2 cm, superior/pharyngeal trigone region with an abutting separate nodular mass, which is 1.4 x 1.1 x 0.6 cm, grossly consistent with possible fibroma. Subjacent to the area of fibroma and leukoplakia, there is a separate confluent area of presumed invasive tumor, 5.5 x 3.2 cm, which extends from the angle of the mandible/right buccal wall (area of double tailed suture) confluent to the base of tongue region (see gross photo). The area of leukoplakia approaches the posterior cut surface to within 0.4 cm, probable invasive mass approaches anterior cut surface of soft tissue/mandible to within 0.5 cm and posteriorly 0.6 cm, as well as base of tongue to within 0.4 cm. The soft tissues are removed from the bony mandible component and there is gross evidence of tumor adherent to the surface of the bone at the angle of the mandible and subsequent sectioning through this area of adherent tumor reveals superficial involvement of cortical bone with no gross evidence of deep invasion, to be confirmed microscopically (cassettes C4 and C5). Sectioning through the region previously described as probable leukoplakia, confirms superficial involvement of the mucosa and sectioning through the abutting adjacent possible fibroma confirms its tan-white homogeneous cut surface without hemorrhage or necrosis. Sectioning through the primary mass reveals verrucoid change, as well as grossly invasive tumor to a depth of 0.7 cm, which correlates with the region previously abutting the mandible (see cassettes C9-11). Step sectioning through the confluent tumor, which approaches base of tongue, reveals invasion to a depth of 0.4 cm and

[page 6 of 9]
approaches to within 0.7 cm of the deep cut surface base of tongue (see cassette C12 and C13).

Sections are submitted as follows:

- C1 anterior mandible margin of surgical resection following decalcification;
- C2 posterior mandible bony margin of resection following decalcification;
- C3 superior pole mandible following decalcification;
- C4-5 sections of mandible with adherent tumor following decalcification;
- C6 area of leukoplakia;
- C7 area of leukoplakia with abutting probable fibroma;
- C8-10 primary mass to include angle of mandible;
- C11 tumor approaching angle of mandible and base of tongue region;
- C12-13 tumor to greatest depth of invasion, base of tongue region.

Part D is received additionally labeled "right buccal fat pad (FSD)" and consists of a single portion of yellow lobulated fibrofatty tissue, 2.5 x 2.5 x 0.3 cm, which is submitted for frozen section evaluation (FSD) with residual frozen section tissue submitted in cassette D.

Part E is received additionally labeled "right sublingual gland (FSE)" and consists of a 3 x 2.5 x 0.3 cm portion of pink-tan to yellow soft tissue, which is submitted for frozen section evaluation (FSE) with residual frozen section tissue submitted in cassette E.

Part F is received additionally labeled "dorsal tongue margin (FSF)" and consists of a partially fragmented portion of pink-tan soft tissue, having aggregate dimensions of 1.8 x 1 x 0.3 cm. These tissues are submitted for frozen section evaluation (FSF) with residual frozen section tissue submitted in cassette F.

Part G is received additionally labeled "right floor of mouth margin (FSG)" and consists of a portion of pink-tan soft tissue, which is 1.5 x 1 x 0.3 cm, which is submitted for frozen section evaluation (FSG) with residual frozen section tissue submitted in cassette G.

Part H is received additionally labeled "anterior gingival margin (FSH)" and consists of multiple fragments of tan-white irregular soft tissues, having aggregate dimensions of 0.6 x 0.5 x 0.2 cm. These tissues are submitted for frozen section evaluation (FSH) with residual frozen section tissue submitted in cassette H.

Part I is received additionally labeled "anterior buccal margin (FSI)" and consists of a partially fragmented portion of pink-tan soft tissue, which is 1.7 x 0.5 x 0.3 cm, which is submitted for frozen section evaluation (FSI) with residual frozen section tissue submitted in cassette I.

[page 7 of 9]
Part J is received additionally labeled "soft palate margin (FSJ)" and consists of a partially fragmented portion of tan-yellow soft tissue, which is 1.2 x 0.6 x 0.3 cm, which is submitted for frozen section evaluation (FSJ) with residual frozen section tissue submitted in cassette J.

Part K is received additionally labeled "superior lip (FSK)" and consists of a single portion of pink-tan irregular soft tissue, which is 1.6 x 0.7 x 0.3 cm, submitted for frozen section evaluation (FSK) with residual frozen section tissue submitted in cassette K.

Part L is received additionally labeled "deep tongue margin (FSL)" and consists of multiple fragments of red-brown soft tissue, having aggregate dimensions of 1.4 x 1 x 0.3 cm. These tissues are submitted for frozen section evaluation (FSL) with residual frozen section tissue submitted in cassette L.

Part M is received additionally labeled "maxillary alveolar ridge (FSM)" and consists of two portions of tan-white apparent strips of mucosa, not otherwise designated, having lengths of 1.5 and 2.5 cm with additional dimensions that average 0.2 x 0.2 cm. These tissues are submitted for frozen section evaluation (FSM) with residual frozen section tissue submitted in cassette M.

Part N is received additionally labeled "glossal tonsillar sulcus (FSN)" and consists of two portions of pink-tan irregular soft tissues, not otherwise designated, having greatest dimensions of 0.6 and 0.8 cm, submitted for frozen section evaluation (FSN) with residual frozen section tissue submitted in cassette N.

Part O is received additionally labeled "right deep buccal margin (FSO)" and consists of a portion of yellow lobulated fibrofatty tissue, which is 1.4 x 1 x 0.3 cm, submitted for frozen section evaluation (FSO) with residual frozen section tissue submitted in cassette O.

Part P is received additionally labeled "right temporalis margin (FSP)" and consists of a single portion of red-brown soft tissue, which is 1.5 x 0.8 x 0.3 cm, submitted for frozen section evaluation (FSP) with residual frozen section tissue submitted in cassette P.

Part Q is received additionally labeled "medial pterygoid margin (FSQ)" and consists of a partially fragmented portion of red-brown soft tissue, which is 2 x 1.3 x 0.3 cm, submitted for frozen section evaluation (FSQ) with residual frozen section tissue submitted in cassette Q.

Part R is received additionally labeled "right parotid mass (FSR+X)" and consists of an ovoid portion of pink-tan soft tissue, 2.4 x 1.4 x 1 cm, having no orientation offered or possible. This tissue is inked and representative section is submitted for frozen section evaluation (FSR) with residual frozen section tissue submitted in cassette R1. The remaining tissue is submitted in cassettes R2 and R3. The specimen has been submitted in its entirety.

[page 8 of 9]
Part S is received additionally labeled "maxillary bone" and consists of apparent multiple fragments of bone admixed with soft tissues, all of which have aggregate dimensions of 1.5 x 1.2 x 0.3 cm. These tissues are submitted in toto in cassette S following decalcification.

Part T is received additionally labeled "right neck dissection, single stitch level 2" and consists of the product of a modified right neck dissection, having dimensions of 6 x 2.8 x 1.5 cm, having a suture at one pole indicating a level II location.

Within the level II there are three probable lymph nodes, which range from 0.8 to 2.2 cm in greatest dimension. There is no gross evidence of tumor involvement within these lymph nodes.

The lymph node candidates are submitted as follows:

- T1 largest lymph node bisected;
- T2 two whole probable lymph nodes.

Within level III there are two whole probable lymph nodes, having greatest dimensions of 0.6 and 1 cm. These lymph node candidates are submitted in cassette T3 with remaining soft tissues from level III submitted in cassette T4 for possible microscopic detection of additional lymph nodes.

Within level IV there are five whole probable lymph nodes, which range from 0.2 to 1 cm in greatest dimension, submitted as follows:

- T5 two whole probable lymph nodes;
- T6 three whole probable lymph nodes;
- T7 remaining soft tissues from level IV for additional microscopic examination and possible detection of additional lymph nodes.

Within level V there are two whole probable lymph nodes, 0.3 cm each in greatest dimension, which are submitted in cassette T8 and remaining soft tissues from level V are submitted in cassette T9 for possible detection of additional lymph nodes.

Microscopic Description:

Histologic examination reveals a right mandibular composite resection with right neck dissection. The composite resection is prominent for a mucosal squamous cell carcinoma demonstrating a papillary surface configuration with extensive keratinization. Invasion into the underlying connective tissue is seen in the form of sheets and islands. Moderate differentiation is noted in areas. This arises from an extensive zone of carcinoma in situ and dysplasia across the surface of the specimen. The carcinoma focally erodes the cortex of the mandible but does not invade the medullary component. The associated lymph node dissection fails to reveal the presence of metastatic disease.

END OF REPORT

Source: NCI Genomic Data Commons file 417bcab1-39ea-48f5-8911-e202a8a84d0e (TCGA-H7-7774.811F0DE6-21B7-4337-BCCB-F1FD10E842D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).